Gene-level copy-number profile of tumor specimen TCGA-27-1832-01A from TCGA case TCGA-27-1832, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.4 years (21,678 days).
Specimen TCGA-27-1832-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.910761b8-816c-4df1-a765-be2fb43f0c20.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-27-1832-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a48b321-a5c7-4cac-94a8-db762cdfed72

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 9,956; copy number 2: 47,111; copy number 3: 2,100; copy number 4: 104; copy number 5: 277; copy number 6: 245.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-27-1832-01A-01D-0591-01): tumor purity 0.6, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,384,255–22,029,594, 22 genes (within-gene range 0–1): IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3.
- chr9:22,646,200–22,824,213, 1 gene: LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr9:25,676,389–25,678,440, 1 gene: TUSC1.
- chr9:26,642,697–26,644,595, 1 gene: AL442639.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 522 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:22,118,236–23,014,130, 17 genes, copy number 5 (within-gene range 2–6): RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, AC005682.2, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A.
- chr7:23,710,203–38,025,695, 284 genes, copy number 5–6 (broad region; genes not listed).
- chr7:39,404,590–48,647,497, 163 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:54,542,325–55,595,006, 21 genes, copy number 5: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2.
- chr21:14,757,588–16,815,688, 37 genes, copy number 6: POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1.

Autosomal genes at a single copy (total copy number 1): 9,944. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
